Somatic mutation profile of tumor specimen 0DN63E from CCDI case PBCBHR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.0 years (5,118 days).
Specimen 0DN63E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82b02e2f-e21d-4160-9c3b-a0aa51653118.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN62Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/578c2108-3f62-4597-8a58-27818c38d20a

The open-access MAF lists 40 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 6, Intron 6, Nonsense Mutation 3, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 68/313 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514606, COSV55605820, COSV55624598; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.5791C>T p.R1931* | Nonsense Mutation (SNP) | VAF 130/330 reads (39%) | catalogued as rs1028186690, COSV51647667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 195/454 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.973C>T p.R325C (on ENST00000399959; = p.R326C on NM_001356.5) | Missense Mutation (SNP) | VAF 289/329 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1555953548, COSV67863531; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARPC2 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 41/626 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1162897270; called by muse, mutect2
- CLU | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 96/467 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs372415096, COSV57066131; called by muse, mutect2, varscan2
- CREBBP | c.4561G>T p.D1521Y | Missense Mutation (SNP) | VAF 130/330 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52117688, COSV99270915; called by muse, mutect2, varscan2
- DHRS13 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 20/502 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs775606900, COSV101129087; called by muse, mutect2
- DNAH8 | c.9197G>A p.R3066H | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs540958336, COSV100543719; called by muse, mutect2, varscan2
- DNAJC7 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 141/324 reads (44%) | catalogued as COSV57269112; called by muse, mutect2, varscan2
- EIF4G1 | c.3092G>A p.R1031H (on ENST00000346169 / NM_198241.3; = p.R836H on NM_004953.5) | Missense Mutation (SNP) | VAF 274/577 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs1391557692, COSV59989479; called by muse, mutect2, varscan2
- FMR1 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54423059; called by muse, mutect2, varscan2
- KDM2A | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 210/237 reads (89%) | SIFT tolerated (0.21); PolyPhen benign (0.06); catalogued as rs746832356, COSV100445528; called by muse, varscan2
- LRP1 | c.7954G>A p.V2652M | Missense Mutation (SNP) | VAF 230/560 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs373019949; called by muse, mutect2, varscan2
- MAGEC3 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 97/177 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs760095164, COSV53580394; called by muse, mutect2, varscan2
- PABPC4L | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 137/569 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.719); catalogued as rs369585514, COSV99081464; called by muse, mutect2, varscan2
- ROR1 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 36/511 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.263); catalogued as rs374512783; called by muse, mutect2
- ARID2 | c.4499C>G p.S1500* | Nonsense Mutation (SNP) | VAF 34/498 reads (7%) | called by muse, mutect2
- BACH2 | c.109T>A p.C37S | Missense Mutation (SNP) | VAF 17/362 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- DDX3X | c.1130C>T p.T377I (on ENST00000399959; = p.T378I on NM_001356.5) | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- MSGN1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 53/374 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR52I2 | c.308T>C p.M103T | Missense Mutation (SNP) | VAF 143/725 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PCDH18 | c.1565C>A p.P522Q | Missense Mutation (SNP) | VAF 64/423 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA2 | c.293A>C p.Q98P | Missense Mutation (SNP) | VAF 82/430 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SELENOT | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 103/649 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- ZNF814 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 90/328 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FCGR2A | c.204T>A p.P68= (on ENST00000271450 / NM_001136219.3; = p.P67= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 198/474 reads (42%) | called by muse, mutect2, varscan2
- KIF9 | c.1731A>G p.K577= (on ENST00000265529 / NM_001377474.1; = p.K512= on NM_022342.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 146/322 reads (45%) | called by muse, mutect2, varscan2
- NFKBID | c.384C>T p.Y128= (on ENST00000396901; = p.Y280= on NM_032721.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 82/470 reads (17%) | catalogued as rs777638414, COSV61727756; called by muse, mutect2, varscan2
- PXDNL | c.2334G>A p.P778= | Silent (SNP) | VAF 58/362 reads (16%) | catalogued as rs770452399, COSV62478593; called by muse, mutect2, varscan2
- REL | c.1251C>T p.H417= | Silent (SNP) | VAF 237/575 reads (41%) | called by muse, mutect2, varscan2
- ZNF462 | c.1470G>A p.Q490= | Silent (SNP) | VAF 142/552 reads (26%) | catalogued as COSV52934178; called by muse, mutect2, varscan2
- ARIH2 | c.256-16436G>A | Intron (SNP) | VAF 243/557 reads (44%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+8797A>G | Intron (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2
- IL15RA | c.89-2450C>G | Intron (SNP) | VAF 81/507 reads (16%) | called by muse, mutect2, varscan2
- KLRD1 | c.315+14C>T | Intron (SNP) | VAF 149/332 reads (45%) | catalogued as rs905489865; called by muse, mutect2, varscan2
- LRSAM1 | c.1348-35C>T | Intron (SNP) | VAF 18/192 reads (9%) | catalogued as rs751963482; called by muse, mutect2
- OR10H5 | c.-42C>T | 5'UTR (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- SMC1A | c.109+529T>C | Intron (SNP) | VAF 74/145 reads (51%) | called by muse, mutect2, varscan2
- ZNF727 | c.-13C>T | 5'UTR (SNP) | VAF 161/643 reads (25%) | catalogued as COSV101473346; called by muse, mutect2, varscan2
